CCDI case PBCJIR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/292d034e-a456-43b0-a105-5425e90729d6

Demographics
Sex at birth: male.

Diagnoses (1)
1. Alveolar soft part sarcoma: ICD-O-3 morphology code: 9581/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 1.1 years (398 days).

Biospecimens (3 samples)
- Sample 0DWYUK: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DWYV4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYWR: Tissue type: Tumor; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
